Somatic mutation profile of tumor specimen TCGA-02-2470-01A (aliquot TCGA-02-2470-01A-01W-0837-08) from TCGA case TCGA-02-2470, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.6 years (21,021 days).
Specimen TCGA-02-2470-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49f1e85c-bf64-427e-9ddb-cc1b405745e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-02-2470-10A (Blood Derived Normal), aliquot TCGA-02-2470-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1b4de36-90e2-45b4-b4b7-7df6cce21def

The open-access MAF lists 87 somatic variants for this specimen: 70 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 16, Frame Shift Ins 4, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 26/166 reads (16%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- PMS2 | c.325dup p.E109Gfs*30 | Frame Shift Ins (INS) | VAF 11/126 reads (9%) | catalogued as rs587781716; ClinVar: pathogenic; called by mutect2, pindel
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 244/529 reads (46%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- AC013489.1 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs1265060262, COSV51550247; called by muse, varscan2
- ACACA | c.3719C>A p.S1240Y | Missense Mutation (SNP) | VAF 45/646 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.254); catalogued as rs1170349765; called by muse, mutect2
- ANO3 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 148/585 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as rs566590577, COSV56781737; called by muse, mutect2, varscan2
- BPIFB2 | c.585C>G p.N195K | Missense Mutation (SNP) | VAF 64/336 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV50063189; called by muse, mutect2, varscan2
- C14orf39 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV58779397, COSV58779744; called by muse, mutect2, varscan2
- CAPN1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs748491783, COSV54196856; called by muse, mutect2, varscan2
- CATSPERD | c.1352A>G p.N451S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.429); catalogued as COSV58464369; called by muse, mutect2, varscan2
- CD96 | c.417C>T p.H139= | Splice Region (SNP) | VAF 31/148 reads (21%) | catalogued as rs368182013; called by muse, mutect2, varscan2
- CT55 | c.368A>G p.E123G | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV52277163; called by muse, mutect2, varscan2
- CTAGE1 | c.2205A>T p.R735S | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV66942964; called by muse, mutect2, varscan2
- DEFB118 | c.78del p.K26Nfs*19 | Frame Shift Del (DEL) | VAF 28/100 reads (28%) | catalogued as rs750510475, COSV53620107; called by mutect2, varscan2
- DNAH17 | c.8764C>T p.R2922C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs367844100; called by muse, mutect2, varscan2
- DRC7 | c.1822G>A p.V608M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.632); catalogued as COSV61053195; called by muse, mutect2, varscan2
- ERGIC1 | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV58595442; called by muse, mutect2, varscan2
- FAM219A | c.492dup p.K165Qfs*39 (on ENST00000445726; = p.K148Qfs*39 on NM_147202.2 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 12/94 reads (13%) | catalogued as rs760074479; called by mutect2, varscan2
- FCGBP | c.4380C>A p.F1460L | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.204); catalogued as COSV55432160, COSV55451368; called by muse, mutect2
- FGF14 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 70/405 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as rs757879324, COSV65935613; called by muse, mutect2, varscan2
- GABRA4 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 66/302 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51923029; called by muse, mutect2, varscan2
- JCAD | c.3317C>T p.A1106V | Missense Mutation (SNP) | VAF 84/183 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as rs772260546, COSV64757970; called by muse, mutect2, varscan2
- KCNA2 | c.450G>T p.W150C | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60369206; called by muse, mutect2, varscan2
- LRRC8B | c.850A>G p.T284A | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV58376707; called by muse, mutect2, varscan2
- MAGEB18 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.291); catalogued as rs1190740592, COSV57463420; called by muse, mutect2, varscan2
- MATK | c.653C>T p.S218L (on ENST00000310132 / NM_139355.3; = p.S219L on NM_002378.4) | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as rs767457416, COSV59553265; called by muse, mutect2, varscan2
- MELK | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 778/1436 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53197176; called by muse, mutect2, varscan2
- MX2 | c.1472A>G p.E491G | Missense Mutation (SNP) | VAF 18/406 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV58095214; called by muse, mutect2
- NKAIN1 | c.193-2A>G p.X65_splice | Splice Site (SNP) | VAF 12/45 reads (27%) | catalogued as rs1296402468, COSV55273897; called by muse, mutect2, varscan2
- NKD1 | c.862dup p.R288Pfs*12 | Frame Shift Ins (INS) | VAF 14/120 reads (12%) | catalogued as rs772439983; called by mutect2, varscan2
- OR10V1 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as rs144835634; called by muse, mutect2, varscan2
- OR5D13 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs369729738, COSV62332785; called by muse, mutect2, varscan2
- PPP1R16B | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55374490; called by muse, mutect2, varscan2
- PSME4 | c.5275C>T p.R1759C | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV66363339; called by muse, mutect2, varscan2
- RAPGEF3 | c.1017G>T p.K339N (on ENST00000389212; = p.K297N on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV50198682; called by muse, mutect2, varscan2
- RFX6 | c.578A>C p.Y193S | Missense Mutation (SNP) | VAF 78/288 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV60583598; called by muse, mutect2, varscan2
- RIMBP2 | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1020820815, COSV55464560; called by muse, mutect2, varscan2
- RYR2 | c.1109T>A p.L370Q | Missense Mutation (SNP) | VAF 71/325 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63664831; called by muse, mutect2, varscan2
- SLCO4C1 | c.2048A>G p.N683S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as rs1208776500; called by muse, mutect2, varscan2
- SMG8 | c.2867T>G p.F956C | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56284070; called by muse, mutect2, varscan2
- SRRM4 | c.1220C>G p.S407C | Missense Mutation (SNP) | VAF 189/540 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV57409399; called by muse, mutect2, varscan2
- SSTR4 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs745839410, COSV54797106; called by muse, mutect2, varscan2
- STAM2 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV55729815; called by muse, mutect2, varscan2
- SVIL | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as rs763834130, COSV100881705, COSV63440239; called by muse, mutect2, varscan2
- SYNJ2 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs772199451, COSV62895768; called by muse, mutect2, varscan2
- TDRD9 | c.3962A>C p.Q1321P | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV59142800; called by muse, mutect2, varscan2
- TNFRSF11A | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 78/359 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as rs376096275; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPO | c.1399G>A p.V467M | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.261); catalogued as rs373267637; called by muse, mutect2
- WDR70 | c.816T>G p.Y272* | Nonsense Mutation (SNP) | VAF 84/332 reads (25%) | catalogued as COSV54267265; called by muse, mutect2, varscan2
- XYLB | c.655A>G p.M219V | Missense Mutation (SNP) | VAF 279/929 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52911693; called by muse, mutect2, varscan2
- ZNF169 | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 11/122 reads (9%) | catalogued as rs200991530; called by muse, mutect2
- ZNF526 | c.1789C>G p.R597G | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV55898496; called by muse, mutect2, varscan2
- ZNF606 | c.1068C>G p.F356L | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs772271108, COSV100357230, COSV62045291; called by muse, mutect2, varscan2
- ARHGEF10 | c.1428G>T p.Q476H (on ENST00000398564; = p.Q451H on NM_014629.4) | Missense Mutation (SNP) | VAF 12/353 reads (3%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACYBP | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2
- CHSY3 | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CNNM2 | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 35/285 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- ESRRG | c.611G>T p.R204L | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FCGBP | c.4382G>T p.C1461F | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITGAM | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIFC1 | c.1635G>T p.Q545H | Missense Mutation (SNP) | VAF 82/1156 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.09); called by muse, mutect2
- LDB1 | c.258C>A p.D86E (on ENST00000425280 / NM_001321612.2; = p.D50E on NM_003893.5) | Missense Mutation (SNP) | VAF 11/371 reads (3%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.805); called by muse, mutect2
- NFIX | c.1248del p.G417Dfs*46 (on ENST00000592199 / NM_001365902.3; = p.G417Dfs*47 on NM_002501.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/77 reads (12%) | called by mutect2, pindel, varscan2
- PRKD3 | c.299G>A p.C100Y | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- RAPGEF1 | c.1319C>A p.P440Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RFX4 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 41/418 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.242); called by muse, mutect2
- SAA2 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SRCAP | c.1765G>T p.A589S | Missense Mutation (SNP) | VAF 32/444 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- TFDP2 | c.877A>T p.S293C (on ENST00000489671 / NM_001178139.2; = p.S233C on NM_006286.5) | Missense Mutation (SNP) | VAF 40/425 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UHRF1 | c.1536C>G p.C512W (on ENST00000612630 / NM_001290050.1; = p.C525W on NM_013282.4) | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C1QTNF5 | c.546C>T p.F182= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV60990603; called by muse, mutect2, varscan2
- COG4 | c.36G>T p.P12= | Silent (SNP) | VAF 60/472 reads (13%) | called by muse, mutect2, varscan2
- DLK1 | c.1137C>T p.G379= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as rs753638016, COSV57990660; called by muse, mutect2, varscan2
- ELOA2 | c.1233A>G p.Q411= | Silent (SNP) | VAF 75/167 reads (45%) | catalogued as rs1480913404, COSV55294183; called by muse, mutect2, varscan2
- IL1R2 | c.748C>T p.L250= | Silent (SNP) | VAF 22/623 reads (4%) | catalogued as COSV60205817; called by muse, mutect2
- NPHS1 | c.852G>A p.P284= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as rs763233132, COSV62286544; called by muse, mutect2, varscan2
- PARP12 | c.1671G>A p.V557= | Silent (SNP) | VAF 135/527 reads (26%) | catalogued as COSV54932424; called by muse, mutect2, varscan2
- PDHA2 | c.585C>T p.G195= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as rs550687466, COSV54777335, COSV54777456; called by muse, mutect2, varscan2
- RPL10 | c.39G>A p.K13= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as rs782767297; called by muse, varscan2
- SAMD4B | c.390C>T p.L130= | Silent (SNP) | VAF 11/259 reads (4%) | catalogued as rs1375394529, COSV58753347; called by muse, mutect2
- SNX8 | c.523C>T p.L175= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs753867783, COSV99770987; called by muse, varscan2
- SNX8 | c.522C>T p.F174= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99771004; called by muse, varscan2
- SPATA31A1 | c.1176G>T p.L392= | Silent (SNP) | VAF 40/96 reads (42%) | called by mutect2, varscan2
- STAM | c.450A>G p.A150= | Silent (SNP) | VAF 139/329 reads (42%) | catalogued as COSV66324951; called by muse, mutect2, varscan2
- TGM5 | c.330G>A p.A110= | Silent (SNP) | VAF 94/252 reads (37%) | catalogued as COSV55008756; called by muse, mutect2, varscan2
- TJP3 | c.186C>T p.N62= | Silent (SNP) | VAF 100/370 reads (27%) | catalogued as rs751459511, COSV53661000; called by muse, mutect2, varscan2
- NEBL-AS1 | chr10:21172392 T>C | 5'Flank (SNP) | VAF 35/74 reads (47%) | catalogued as COSV68841139; called by muse, mutect2, varscan2
